Somatic mutation profile of tumor specimen C3N-04273-01 (aliquot CPT0245230010) from CPTAC case C3N-04273, project CPTAC-3 (Oropharynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 73.6 years (26,874 days).
Specimen C3N-04273-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oropharynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b40e4da-42f9-40ee-992d-e373e56cc1c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04273-31 (Blood Derived Normal), aliquot CPT0245290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca3ec2ce-9a6c-4564-8fff-1e135a43c329

The open-access MAF lists 127 somatic variants for this specimen: 88 protein-altering or splice-affecting, 21 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 21, Intron 8, Nonsense Mutation 5, RNA 4, Frame Shift Del 3, 5'UTR 2, Splice Region 2, 3'UTR 2, Splice Site 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 35/225 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50461559, COSV50532653; called by muse, mutect2, varscan2
- AHRR | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 592/862 reads (69%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV57087640; called by muse, mutect2, varscan2
- ANO5 | c.1155C>A p.F385L | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV61086936; called by mutect2, varscan2
- APC | c.3058G>T p.E1020* | Nonsense Mutation (SNP) | VAF 53/92 reads (58%) | catalogued as CM990156, COSV57355940; called by mutect2, varscan2
- ARHGAP30 | c.1645G>C p.G549R | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); catalogued as COSV63515792; called by muse, mutect2
- BRWD3 | c.4335G>T p.R1445S | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.115); catalogued as rs369328692; called by muse, mutect2, varscan2
- CD22 | c.843G>T p.K281N | Missense Mutation (SNP) | VAF 28/568 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757854964; called by muse, mutect2
- CDH23 | c.4394G>T p.G1465V | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.421); catalogued as COSV56454959; called by muse, mutect2, varscan2
- CEP76 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 42/98 reads (43%) | catalogued as rs1258065223; called by muse, mutect2, varscan2
- EPB41L2 | c.2669C>G p.S890C | Missense Mutation (SNP) | VAF 79/239 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61358698; called by muse, mutect2, varscan2
- KIF20B | c.3491A>G p.K1164R (on ENST00000371728 / NM_001284259.2; = p.K1124R on NM_016195.4) | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as rs1264594745; called by muse, mutect2, varscan2
- KMT2B | c.2462G>A p.S821N | Missense Mutation (SNP) | VAF 45/407 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs767324610; called by muse, mutect2, varscan2
- KMT2D | c.7769C>T p.S2590L | Missense Mutation (SNP) | VAF 104/267 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs760007799, COSV56421757; called by muse, mutect2, varscan2
- LRRC23 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 15/221 reads (7%) | catalogued as rs782137170; called by muse, mutect2
- NYNRIN | c.3052G>A p.D1018N | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.018); catalogued as COSV101230591; called by muse, mutect2, varscan2
- OR2T3 | c.761T>C p.L254P | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.864); catalogued as rs1345612246; called by muse, mutect2, varscan2
- OTOP3 | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 64/124 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.379); catalogued as COSV60914941; called by muse, mutect2
- PCLO | c.15254G>A p.R5085Q | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs569045178, COSV61643507, COSV61654875; called by muse, mutect2, varscan2
- PGM5 | c.1427C>T p.T476M | Missense Mutation (SNP) | VAF 20/310 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.336); catalogued as rs200812025; called by muse, mutect2
- PHF6 | c.128A>G p.H43R | Missense Mutation (SNP) | VAF 68/108 reads (63%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as rs1273843884; called by muse, mutect2, varscan2
- PROKR1 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752055466; called by muse, mutect2, varscan2
- RBMXL3 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 47/70 reads (67%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.84); catalogued as rs781912638, COSV100406329; called by muse, mutect2, varscan2
- TPO | c.2578G>A p.G860R | Missense Mutation (SNP) | VAF 159/521 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as rs556552435, CM076570, COSV61103154; called by muse, mutect2, varscan2
- TTN | c.19105C>G p.R6369G (on ENST00000591111; = p.R5442G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | PolyPhen possibly damaging (0.645); catalogued as COSV60086827; called by muse, mutect2, varscan2
- ZNF469 | c.10299G>C p.Q3433H (on ENST00000437464; = p.Q3461H on NM_001367624.2) | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as COSV71259359; called by muse, mutect2, varscan2
- ZNF568 | c.523T>G p.F175V | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100451468; called by muse, mutect2, varscan2
- ZNF701 | c.1156C>T p.H386Y (on ENST00000301093; = p.H320Y on NM_018260.3) | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs1021805328, COSV56524795; called by muse, mutect2, varscan2
- ZNF787 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54417531; called by muse, mutect2, varscan2
- ACTR10 | c.993A>T p.K331N | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ADAMTS3 | c.1406C>A p.P469Q | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ANAPC4 | c.339G>T p.M113I | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- ASB3 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ASCC3 | c.3193A>G p.I1065V | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- ATR | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- AUP1 | c.437G>A p.C146Y | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- BAIAP3 | c.2928G>A p.K976= | Splice Region (SNP) | VAF 51/160 reads (32%) | called by muse, mutect2, varscan2
- C19orf12 | c.82G>T p.G28W (on ENST00000392278 / NM_001031726.3; = p.G17W on NM_031448.6) | Missense Mutation (SNP) | VAF 250/1368 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- C4orf54 | c.2961G>T p.M987I | Missense Mutation (SNP) | VAF 98/207 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- CD163 | c.1897C>A p.P633T | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.134); called by muse, mutect2
- CHUK | c.1945G>C p.E649Q | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CLNS1A | c.325A>G p.I109V | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, varscan2
- COQ5 | c.878C>A p.S293Y | Missense Mutation (SNP) | VAF 102/247 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- DNAH5 | c.11072G>A p.R3691K | Missense Mutation (SNP) | VAF 280/451 reads (62%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DOP1A | c.563G>A p.S188N | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EIF5A | c.403-30_407del p.X135_splice | Splice Site (DEL) | VAF 35/167 reads (21%) | called by mutect2, pindel
- GOLGA6D | c.1589C>A p.A530D | Missense Mutation (SNP) | VAF 50/471 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.009); called by mutect2, varscan2
- HIVEP1 | c.6928G>A p.E2310K | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.041); called by muse, mutect2
- IGSF3 | c.2245G>T p.G749C (on ENST00000369486 / NM_001007237.3; = p.G769C on NM_001542.4) | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2
- IKBKE | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- INPPL1 | c.1694G>T p.G565V | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KAT6B | c.3748A>T p.K1250* | Nonsense Mutation (SNP) | VAF 75/216 reads (35%) | called by muse, mutect2, varscan2
- KCNU1 | c.2462C>G p.T821S | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- KIAA1549 | c.5764C>A p.H1922N (on ENST00000422774 / NM_001164665.2; = p.H1906N on NM_020910.3) | Missense Mutation (SNP) | VAF 72/401 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIFC3 | c.20C>G p.T7R | Missense Mutation (SNP) | VAF 61/116 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- KIRREL2 | c.2095C>A p.P699T | Missense Mutation (SNP) | VAF 108/852 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- KMT2C | c.10544_10549del p.F3515_P3517delinsS | In Frame Del (DEL) | VAF 47/248 reads (19%) | called by mutect2, pindel, varscan2
- KNL1 | c.2233A>T p.S745C (on ENST00000346991 / NM_170589.5; = p.S719C on NM_144508.5) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); called by mutect2, varscan2
- LIFR | c.3067G>C p.D1023H | Missense Mutation (SNP) | VAF 60/686 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); called by muse, mutect2
- LSR | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 248/1321 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- MAT1A | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 149/438 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MS4A2 | c.479A>G p.H160R | Missense Mutation (SNP) | VAF 133/346 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- MYO9A | c.6452A>C p.Y2151S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDUFB6 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- OSR1 | c.215T>G p.V72G | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PCDHB12 | c.1221A>T p.R407S | Missense Mutation (SNP) | VAF 21/252 reads (8%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.006); called by muse, mutect2
- PLEC | c.4797G>T p.E1599D (on ENST00000322810 / NM_201380.4; = p.E1489D on NM_000445.5) | Missense Mutation (SNP) | VAF 236/856 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PMPCA | c.1421C>A p.P474Q | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PPP1R1B | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RB1 | c.899dup p.M300Ifs*10 | Frame Shift Ins (INS) | VAF 30/57 reads (53%) | called by pindel, varscan2
- RBL2 | c.1779C>G p.I593M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- RUSC1 | c.1514C>T p.A505V (on ENST00000368352 / NM_001105203.2; = p.A36V on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 222/329 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- RYR1 | c.14608G>A p.E4870K | Missense Mutation (SNP) | VAF 325/1766 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC22A5 | c.1052+6T>A | Splice Region (SNP) | VAF 90/161 reads (56%) | called by muse, mutect2, varscan2
- SMIM10 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 78/117 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SNX13 | c.1720C>A p.H574N | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SPATA31D1 | c.3242C>A p.T1081K | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SPEN | c.10339_10340del p.L3447Sfs*30 | Frame Shift Del (DEL) | VAF 61/252 reads (24%) | called by pindel, varscan2
- ST8SIA5 | c.610G>T p.V204L | Missense Mutation (SNP) | VAF 47/130 reads (36%) | PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- TLCD3A | c.600C>G p.Y200* | Nonsense Mutation (SNP) | VAF 129/453 reads (28%) | called by muse, mutect2, varscan2
- TOGARAM1 | c.4621G>T p.D1541Y | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TP53 | c.148del p.I50Lfs*73 | Frame Shift Del (DEL) | VAF 70/222 reads (32%) | called by mutect2, pindel, varscan2
- UNC13C | c.5697-1G>C p.X1899_splice | Splice Site (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- UNC79 | c.7460A>G p.E2487G (on ENST00000393151 / NM_001346218.2; = p.E2310G on NM_020818.5) | Missense Mutation (SNP) | VAF 88/263 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- WDFY4 | c.6461T>A p.V2154E | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ZNF184 | c.1838C>A p.P613H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ZNF227 | c.426C>G p.D142E | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.97); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF763 | c.268G>T p.D90Y (on ENST00000358987 / NM_001367172.2; = p.D93Y on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF770 | c.2067_2070del p.V690Cfs*23 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | called by mutect2, pindel, varscan2
- ATP7B | c.2325C>T p.A775= | Silent (SNP) | VAF 20/312 reads (6%) | catalogued as rs755218710, COSV54437474; called by muse, mutect2
- BRD2 | c.2004A>T p.I668= | Silent (SNP) | VAF 144/364 reads (40%) | called by muse, mutect2, varscan2
- CADPS2 | c.1017T>C p.R339= | Silent (SNP) | VAF 23/109 reads (21%) | called by muse, mutect2, varscan2
- CARD11 | c.60C>T p.D20= | Silent (SNP) | VAF 82/266 reads (31%) | catalogued as rs140217679; called by muse, mutect2, varscan2
- CDH19 | c.996T>C p.I332= | Silent (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- DNAH5 | c.12885G>T p.V4295= | Silent (SNP) | VAF 14/264 reads (5%) | called by muse, mutect2
- DSP | c.945C>T p.R315= | Silent (SNP) | VAF 60/211 reads (28%) | called by muse, mutect2, varscan2
- ESCO1 | c.2490A>G p.V830= | Silent (SNP) | VAF 48/76 reads (63%) | catalogued as rs1455680031; called by muse, mutect2, varscan2
- FEM1A | c.516G>A p.Q172= | Silent (SNP) | VAF 13/282 reads (5%) | called by muse, mutect2
- GRM7 | c.828C>T p.D276= | Silent (SNP) | VAF 74/137 reads (54%) | called by muse, mutect2, varscan2
- ITPR3 | c.1932C>T p.A644= | Silent (SNP) | VAF 54/197 reads (27%) | called by muse, mutect2, varscan2
- MAGI2 | c.396C>T p.N132= | Silent (SNP) | VAF 33/94 reads (35%) | called by muse, mutect2, varscan2
- MMP7 | c.549G>A p.G183= | Silent (SNP) | VAF 62/149 reads (42%) | catalogued as rs1165590311, COSV99497174; called by muse, mutect2, varscan2
- NEUROG3 | c.6G>T p.T2= | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as rs751389618; called by muse, mutect2, varscan2
- PCDH8 | c.1725C>G p.L575= | Silent (SNP) | VAF 14/175 reads (8%) | called by muse, mutect2
- PHF8 | c.3159C>T p.H1053= (on ENST00000357988 / NM_001184896.1; = p.H1017= on NM_015107.3) | Silent (SNP) | VAF 29/48 reads (60%) | catalogued as rs1557082674; called by muse, mutect2, varscan2
- PLCB1 | c.3579G>T p.V1193= | Silent (SNP) | VAF 50/305 reads (16%) | catalogued as COSV100572527; called by muse, mutect2, varscan2
- PPARGC1B | c.900C>T p.P300= | Silent (SNP) | VAF 96/153 reads (63%) | catalogued as rs141866379; called by muse, mutect2, varscan2
- SH3BGRL2 | c.159C>G p.V53= | Silent (SNP) | VAF 30/129 reads (23%) | catalogued as rs773554244; called by muse, varscan2
- SLC6A19 | c.129C>T p.L43= | Silent (SNP) | VAF 141/808 reads (17%) | catalogued as rs748780849; called by muse, mutect2, varscan2
- ZNF141 | c.1140G>A p.R380= | Silent (SNP) | VAF 59/108 reads (55%) | catalogued as rs1560199621; called by muse, mutect2, varscan2
- AHCY | c.219+120G>T | Intron (SNP) | VAF 192/303 reads (63%) | called by muse, mutect2, varscan2
- CA8 | c.-11G>T | 5'UTR (SNP) | VAF 131/431 reads (30%) | called by muse, mutect2, varscan2
- CEP41 | c.*1170G>A | 3'UTR (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- CEP41 | c.*400C>T | 3'UTR (SNP) | VAF 73/293 reads (25%) | called by muse, mutect2, varscan2
- CREM | c.698-6257C>T | Intron (SNP) | VAF 26/95 reads (27%) | catalogued as rs745858944; called by muse, mutect2, varscan2
- CXADRP2 | n.437T>C | RNA (SNP) | VAF 6/58 reads (10%) | catalogued as rs759133672; called by mutect2, varscan2
- DDX12P | n.2700G>A | RNA (SNP) | VAF 8/122 reads (7%) | catalogued as rs1201284836; called by muse, mutect2
- HBE1 | c.-267+102184C>A | Intron (SNP) | VAF 65/155 reads (42%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1737G>T | RNA (SNP) | VAF 67/661 reads (10%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+1786C>G | Intron (SNP) | VAF 98/132 reads (74%) | catalogued as rs1205831657; called by muse, mutect2, varscan2
- LARP7 | c.-2-186A>G | Intron (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- OR2A13P | n.151G>T | RNA (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- PFKFB3 | c.1515+1869A>T | Intron (SNP) | VAF 61/225 reads (27%) | called by muse, mutect2, varscan2
- PI4KAP2 | chr22:21475227 TCTGGCCGCGAAAACAGGGCAGGCCCGTGTCCAAC>GCCGCGAAAACAGGGCAGGCCCGTGTCCAACA | 3'Flank (DEL) | VAF 19/102 reads (19%) | called by mutect2*, pindel, varscan2*
- SPATA13 | c.-222-26163G>A | Intron (SNP) | VAF 153/233 reads (66%) | called by muse, mutect2, varscan2
- STRA8 | c.420-12G>T | Intron (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- SYT11 | c.-4C>T | 5'UTR (SNP) | VAF 29/153 reads (19%) | called by muse, mutect2, varscan2
- ZNF561 | chr19:9621577 T>G | 5'Flank (SNP) | VAF 44/71 reads (62%) | called by muse, mutect2, varscan2
